Somatic mutation profile of tumor specimen TCGA-C5-A2LV-01A (aliquot TCGA-C5-A2LV-01A-11D-A18J-09) from TCGA case TCGA-C5-A2LV, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 36.8 years (13,447 days).
Specimen TCGA-C5-A2LV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8bdf71a8-44e6-466c-9826-54614c6bbd6f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-C5-A2LV-10A (Blood Derived Normal), aliquot TCGA-C5-A2LV-10A-01D-A18J-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fc18c9c9-fcc1-4d31-a722-cb7c0352bb05

The open-access MAF lists 76 somatic variants for this specimen: 58 protein-altering or splice-affecting, 17 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 17, Nonsense Mutation 6, In Frame Ins 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGAP44 | c.2105C>T p.S702L | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.079); catalogued as rs768572384, COSV52402867; called by muse, mutect2, varscan2
- B4GALNT4 | c.853G>T p.E285* | Nonsense Mutation (SNP) | VAF 3/43 reads (7%) | catalogued as rs1463337424; called by muse, mutect2
- CARD10 | c.355C>T p.R119C | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1417636892; called by muse, mutect2, varscan2
- CD53 | c.479C>G p.S160C | Missense Mutation (SNP) | VAF 40/186 reads (22%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.977); catalogued as COSV54762230; called by muse, mutect2, varscan2
- CELSR1 | c.7355C>T p.A2452V | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs770141005; called by muse, mutect2, varscan2
- CHST2 | c.1456G>A p.A486T | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.574); catalogued as COSV58886674; called by muse, mutect2, varscan2
- CYTH3 | c.851G>A p.R284H (on ENST00000396741; = p.R283H on NM_004227.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV60362817; called by muse, mutect2, varscan2
- DDR1 | c.2630C>T p.P877L (on ENST00000324771; = p.P840L on NM_001954.4) | Missense Mutation (SNP) | VAF 35/54 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776556090, COSV61320137; called by muse, mutect2, varscan2
- DENND1A | c.2102G>A p.R701Q | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs769475609; called by muse, mutect2, varscan2
- EFTUD2 | c.2755C>T p.R919C | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV53655184; called by muse, mutect2, varscan2
- FLRT3 | c.781C>T p.R261W | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.697); catalogued as rs564318429, COSV53958879; called by muse, mutect2, varscan2
- FUT5 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs781164561; called by muse, mutect2, varscan2
- GABRA5 | c.688C>A p.Q230K | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.405); catalogued as rs1266663568, COSV59480395; called by muse, mutect2, varscan2
- GRAMD4 | c.1313G>A p.R438H | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs767243912; called by muse, mutect2, varscan2
- GRXCR2 | c.450_451insTCT p.E150_E151insS | In Frame Ins (INS) | VAF 15/46 reads (33%) | catalogued as COSV100939984; called by mutect2, pindel, varscan2
- HEPH | c.2596G>C p.E866Q (on ENST00000343002; = p.E599Q on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.271); catalogued as COSV100295429; called by muse, mutect2, varscan2
- ITGAE | c.651C>A p.D217E | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV99560855; called by muse, mutect2
- KCNJ11 | c.11G>A p.R4H | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769283457, COSV56846454; called by muse, mutect2, varscan2
- KIAA0586 | c.4102C>T p.R1368W (on ENST00000619416 / NM_001244190.2; = p.R1307W on NM_014749.5) | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs1015444951; called by muse, mutect2, varscan2
- KIAA2013 | c.1426G>A p.V476M | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs1307721202, COSV64860904, COSV64861228; called by muse, mutect2, varscan2
- KIF20B | c.4447G>T p.E1483* (on ENST00000371728 / NM_001284259.2; = p.E1443* on NM_016195.4) | Nonsense Mutation (SNP) | VAF 3/34 reads (9%) | catalogued as COSV99589873; called by muse, mutect2
- KMT2B | c.1684G>T p.V562F | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.009); catalogued as COSV52892061; called by muse, mutect2
- MYH11 | c.995C>T p.A332V | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV55566130; called by muse, mutect2, varscan2
- OR4K2 | c.196C>T p.L66F | Missense Mutation (SNP) | VAF 38/150 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1342463376; called by muse, mutect2, varscan2
- PCLO | c.4133C>A p.P1378Q | Missense Mutation (SNP) | VAF 30/51 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV61645865; called by muse, mutect2, varscan2
- PCSK4 | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 53/178 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142181980; called by muse, mutect2, varscan2
- PLAA | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.986); catalogued as rs760173766; called by muse, mutect2, varscan2
- RNF167 | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs754895476; called by muse, mutect2, varscan2
- SI | c.1810G>A p.D604N | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as COSV52301103; called by muse, mutect2, varscan2
- SLC17A8 | c.211G>A p.G71S | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.223); catalogued as rs769738794, COSV60124909; called by muse, mutect2, varscan2
- SPSB4 | c.356C>T p.T119M | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779337757, COSV60144591; called by mutect2, varscan2
- TEX14 | c.1831G>C p.E611Q (on ENST00000240361 / NM_001201457.2; = p.E605Q on NM_031272.5) | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.48); PolyPhen benign (0.067); catalogued as COSV53614969; called by muse, mutect2, varscan2
- THUMPD3 | c.31C>T p.L11F | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.007); catalogued as rs1367177576; called by muse, mutect2
- ACCS | c.1276G>C p.E426Q | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- ACTL6B | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADD2 | c.120C>A p.D40E | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- CSNK1A1L | c.511C>A p.Q171K | Missense Mutation (SNP) | VAF 54/143 reads (38%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ESPL1 | c.5272G>C p.D1758H | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GABRB3 | c.1030G>T p.E344* | Nonsense Mutation (SNP) | VAF 51/131 reads (39%) | called by muse, mutect2, varscan2
- KCTD6 | c.542C>T p.P181L | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- LARP7 | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- MYH6 | c.3403G>C p.E1135Q | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NBPF1 | c.107G>A p.R36K | Missense Mutation (SNP) | VAF 24/176 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- NUDC | c.743T>C p.I248T | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- OSBPL1A | c.1112A>C p.Q371P | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- PPP1R15A | c.545C>T p.S182L | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- PTPRM | c.37G>T p.G13* | Nonsense Mutation (SNP) | VAF 19/55 reads (35%) | called by muse, mutect2, varscan2
- RB1CC1 | c.943C>T p.Q315* | Nonsense Mutation (SNP) | VAF 53/82 reads (65%) | called by muse, mutect2, varscan2
- RYR2 | c.2725G>C p.D909H | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- SCN3A | c.1768G>C p.E590Q | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SDK1 | c.2408_2409del p.G803Vfs*39 | Frame Shift Del (DEL) | VAF 9/51 reads (18%) | called by mutect2, pindel, varscan2
- SEMA4B | c.1473C>G p.I491M | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- SLC22A4 | c.113C>T p.S38L | Missense Mutation (SNP) | VAF 26/45 reads (58%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- SYNPO2 | c.1252G>C p.E418Q | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- UNC80 | c.281C>G p.S94* | Nonsense Mutation (SNP) | VAF 28/49 reads (57%) | called by muse, mutect2, varscan2
- VKORC1L1 | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- ZNF134 | c.1138G>C p.D380H | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- ZNF581 | c.47C>T p.S16F | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- BNIPL | c.396G>A p.S132= | Silent (SNP) | VAF 20/76 reads (26%) | catalogued as rs768210905; called by muse, mutect2, varscan2
- CACNA1G | c.2535G>A p.V845= | Silent (SNP) | VAF 27/62 reads (44%) | catalogued as rs749680889; called by muse, mutect2, varscan2
- DNAH3 | c.21C>G p.L7= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV51786262; called by muse, mutect2, varscan2
- FAM32A | c.195C>T p.F65= | Silent (SNP) | VAF 15/54 reads (28%) | called by muse, mutect2, varscan2
- FCGBP | c.4347C>T p.P1449= | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as rs141817498; called by muse, mutect2
- FRMPD1 | c.1602C>T p.C534= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as rs764948858; called by muse, mutect2, varscan2
- IRAK2 | c.1158C>T p.F386= | Silent (SNP) | VAF 18/46 reads (39%) | called by muse, mutect2, varscan2
- LAMP2 | c.1200C>G p.L400= | Silent (SNP) | VAF 15/62 reads (24%) | called by muse, mutect2, varscan2
- MED23 | c.3147G>A p.L1049= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as rs1420721998; called by muse, mutect2, varscan2
- MRGPRX1 | c.783C>T p.S261= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as rs755616556, COSV57106086; called by muse, mutect2, varscan2
- MUC16 | c.16557C>T p.A5519= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as COSV67485050; called by muse, mutect2, varscan2
- NHSL2 | c.498G>A p.E166= (on ENST00000510661; = p.E532= on NM_001013627.2) | Silent (SNP) | VAF 4/20 reads (20%) | called by muse, mutect2, varscan2
- PCDHB13 | c.1233A>G p.R411= | Silent (SNP) | VAF 17/57 reads (30%) | called by muse, mutect2, varscan2
- PSG1 | c.60C>T p.L20= | Silent (SNP) | VAF 27/132 reads (20%) | called by muse, mutect2, varscan2
- RYR2 | c.10257C>T p.F3419= | Silent (SNP) | VAF 22/51 reads (43%) | catalogued as rs748715725, COSV63681983; ClinVar: likely benign; called by muse, mutect2, varscan2
- STRADB | c.504C>T p.A168= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as rs768465769; called by muse, mutect2, varscan2
- TMEM63C | c.1947C>T p.N649= | Silent (SNP) | VAF 17/111 reads (15%) | catalogued as rs752675016; called by muse, mutect2, varscan2
- SSPOP | n.8079G>T | RNA (SNP) | VAF 3/10 reads (30%) | catalogued as rs1327476406, COSV100947289; called by muse, mutect2
